Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A3I5, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A3I5-01B (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

* Final Report *

Result type: Surgical Pathology Report
Result date:
Result status: Signed
Result title: Surgical Pathology Report
Performed by:
Verified by:
Encounter info:

* Final Report *

Clinical History

Right thyroid nodule

Specimen

- #1 Right thyroid lymph node
- #2 Right lobe, isthmus, Level 6 lymph nodes
- #3 Right periesophageal lymph node
- #4 Left lobe, stitch marks upper pole
- #5 Anterior compartment

Reviewed Initials	RW	

100-0-3
carcinoma, papillary, follicular variant 8340/3
Site: thyroid, NOS C73.9 12/21/11

Gross Examination

#1 The specimen is received fresh labeled right thyroid lymph node. Received is a single fragment of pink tan soft tissue measuring 0.5 x 0.3 x 0.2 cm. The lymph node is bisected and a touch preparation is made. It is entirely submitted for Frozen Section.

#2 Received fresh labeled right lobe, isthmus, level 6 lymph nodes is a 41.4 gm, 5.7 x 3.7 x 3.5 cm thyroid lobe. The isthmus is approximately 2.0 x 1.2 x 0.7 cm. Attached to the lower pole is a 2.5 x 2.0 x 0.7 cm portion of tan-yellow fibroadipose tissue. The outer surface is inked black. The tissue is serially sectioned to demonstrate a 4.5 x 3.0 x 3.0 cm well circumscribed nodule with a firm, tan, glistening, and focally hemorrhagic cut surface. Within the nodule is a 0.6 cm firm, white-tan fibrous area. The nodule has a thin fibrous capsule in areas which grossly abuts the black-inked outer surface. At the lower pole are five additional circumscribed nodules which have a predominantly tan, glistening cut surface, some with focal areas of hemorrhage and calcification. The nodules involve greater than 90% of the thyroid lobe. The small amount of uninvolved parenchyma is dark red-brown. Within the fibroadipose tissue, extending from the lower pole, are multiple lymph node candidates, up to 0.8 cm in greatest dimension. Eighteen representative sections submitted in ten "A"- "J". Block summary: "A"- "C" sections from the largest nodule; "D"- "F" representative sections of each of the five additional nodules; "G" uninvolved parenchyma; "H"- "J" lymph node candidates as follows; "H" multiple individual; "I" two individual; "J" one bisected. Following the explicit written consent of the patient, tissue is submitted to the

#3 Labeled right periesophageal lymph node is a 1.7 x 0.9 x 0.5 cm aggregate of

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
* Final Report *

two fragments of fibroadipose tissue. There are three lymph node candidates within the tissue, up to 0.3 cm in greatest dimension. The specimen is entirely submitted as five sections in two: "A", "B". Block summary: "A" three intact lymph node candidates; "B" remaining adipose tissue.

#4 Received fresh labeled left lobe, stitch marks upper pole, is a 10.1 gm, 5.0 x 3.0 x 2.3 cm thyroid lobectomy specimen, oriented as stated above. The capsule is red-purple and intact. It is entirely inked black, and sectioning demonstrates a multinodular cut surface with approximately 8-10 nodules, ranging from 0.3-1.5 cm in greatest dimension. The largest nodule is white-yellow and focally calcified and is located within the upper pole. There is one smaller nodule which has a similar appearance (0.4 cm in greatest dimension) and is located within the inferior pole. The remainder of the nodules are all pale pink-tan and soft. There is a minimal amount of uninvolved parenchyma within the inferior pole (less than 5% total). Six sections are submitted in five: "A"- "E". Block summary: "A" largest nodule, upper pole; "B"- "D" representative of tan, soft nodules from superior to inferior, respectively; "E" uninvolved parenchyma, lower pole.

#5 Labeled anterior compartment is a 0.5 x 0.2 x 0.2 cm fragment of adipose tissue with a 0.1 cm in greatest dimension pink lymph node candidate. It is entirely submitted in one cassette.

Frozen Section Diagnosis

#1 LYMPH NODE, RIGHT THYROID EXCISION (1TP, 1FS): NEGATIVE FOR CARCINOMA.
REPORTED TO DR. AT

Microscopic Examination

#1-5 Microscopic examination performed. Select slides are reviewed with Dr.

Final Diagnosis

#1 LYMPH NODE, RIGHT THYROID, EXCISION: ONE LYMPH NODE, NEGATIVE FOR CARCINOMA

(0/1).

#2 THYROID, RIGHT LOBE, ISTHMUS, LEVEL 6 LYMPH NODES, EXCISION:
MULTIFOCAL PAPILLARY CARCINOMA, FOLLICULAR VARIANT.
TUMOR SIZE: LARGEST FOCUS MEASURES 4.5 X 3.0 X 3.0 CM.
SURGICAL MARGIN STATUS: NEGATIVE FOR CARCINOMA.
TUMOR CAPSULE: PARTIALLY ENCAPSULATED.
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) VASCULAR SPACE STATUS:
NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED.
EXTRATHYROIDAL EXTENSION: NOT IDENTIFIED.
LEVEL 6 LYMPH NODE STATUS: NINE LYMPH NODES, NEGATIVE FOR CARCINOMA

(0/9).

ADDITIONAL FINDINGS: LYMPHOCYTIC THYROIDITIS.
PATHOLOGIC STAGE (TNM CLASSIFICATION): pT3 pN0.

#3 LYMPH NODE, RIGHT PERIESOPHAGEAL, EXCISION: THREE LYMPH NODES, NEGATIVE

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surgical Pathology Report

* Final Report *

FOR CARCINOMA (0/3).
#4 THYROID, LEFT LOBE, EXCISION:
PAPILLARY CARCINOMA, CLASSICAL VARIANT.
TUMOR SIZE: 0.9 CM.
SURGICAL MARGIN STATUS: NEGATIVE FOR CARCINOMA.
TUMOR CAPSULE: PARTIALLY ENCAPSULATED.
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) VASCULAR SPACE STATUS:
NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED.
EXTRATHYROIDAL EXTENSION: NOT IDENTIFIED.
ADDITIONAL FINDINGS: PARATHYROID TISSUE PRESENT, LYMPHOCYTIC
THYROIDITIS.

#5 ANTERIOR COMPARTMENT, EXCISION: ONE LYMPH NODE, NEGATIVE FOR CARCINOMA
(0/1).

Signature Line

Signed by:
ELECTRONIC SIGNATURE

Ordering Provider

Ordering Physician:

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file df776395-cef0-4678-9451-2663ff611b72 (TCGA-FY-A3I5.148DA57C-7105-4189-9494-114FBF524F60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).